Surgical pathology report (de-identified scan), TCGA case TCGA-A5-A0GE, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Cedars Sinai, specimen TCGA-A5-A0GE-01A (Primary Tumor).

[page 1 of 3]
ICD-0-3

Adenocarcinoma,
Endometrioid, NOS

Page 1 of 3

838013

lw

11/22/10

Site: Endometrium C54.1

PATHOLOGY REP

PATH #:

A/S:

Rec:

Col:

Soc. Sec. No:

Location:

Pathologist:

Assistant:

Attending MD:

Ordering MD:

Copies To:

=====

DIAGNOSIS:

1. UTERUS, BILATERAL TUBES AND OVARIES (TOTAL ABDOMINAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY):
- Endometrial adenocarcinoma, endometrioid type, FIGO grade 2, nuclear grade 2-3
- A rare microscopic focus of possible early myometrial invasion is noted in foci where the myometrium measures 2.2 cm in thickness
- Tumor measures 3.4 x 2.9 cm in greatest dimension, and lies along the posterior wall
- No extension into endocervical tissue is identified
- Parametrial tissue is negative for tumor
- Background of proliferative phase endometrium
- Leiomyoma, small, intramural
- Focal squamous metaplasia associated with chronic cervicitis, cervix
- Bilateral fallopian tubes with no significant histopathologic changes (no evidence of tumor involvement)
- Right ovary demonstrating multiple hemorrhagic follicle cysts with no evidence of tumor involvement
- Left ovary demonstrating multiple follicle cysts
- Pathologic stage T1b
2. RIGHT PELVIC LYMPH NODE, BIOPSY:
- Solitary pelvic lymph node with no metastatic carcinoma identified
3. RIGHT PERIAORTIC LYMPH NODE:
- Four (4) lymph nodes with no metastatic carcinoma identified
4. LEFT PELVIC LYMPH NODE, BIOPSY:
- Two (2) lymph nodes with no metastatic carcinoma identified
5. LEFT PERIAORTIC LYMPH NODE, BIOPSY:
- Solitary lymph node with no metastatic carcinoma identified
6. APPENDIX, APPENDECTOMY:
- Appendix with no significant histopathologic changes

=====

HISTORY: Endometrial carcinoma

MICROSCOPIC:

See Diagnosis.

GROSS:

1. UTERUS, TUBES, OVARIES

[page 2 of 3]
Labeled with the patient's name, labeled as designated on the specimen requisition form, and received in formalin is a uterus bilateral adnexa which weighs 130 grams. The uterine corpus is symmetric, measuring 7.8 cm superior to inferior, 5.0 cm cornu to cornu, and 5.0 cm anterior to posterior. The serosa is tan-red and smooth. The cervix has a length of 3.7 cm and a diameter of 3.8 cm. There is a 0.5 cm slit-like patent os. The vaginal cuff ranges in thickness from 0.9 cm anteriorly to 0.9 cm posteriorly. There are no apparent gross abnormalities. The ectocervical mucosa is ulceration. The transformation zone is indistinct. The endocervical canal is 2.7 cm in length and is contains 1 soft tan polyp(s), 0.3 x 0.3 x 0.2 cm. in greatest dimension. On sectioning multiple mucus-filled nabothian cysts are identified. The endometrial cavity is 3.5 cm in length, 2.7 cm in width, and is lined by a hemorrhagic red-tan endometrium with a thickness of 0.2 cm. The endometrium contains a friable tan-pink, focally hemorrhagic polypoid tumor, measuring 3.4 x 2.9 x 1.0 cm in greatest dimension and on sectioning extends 0.7 cm into the posterior myometrium. The myometrium is 2.2 cm in maximum thickness. The myometrium is grossly unremarkable. The right ovary measures 2.7 x 2.5 x 2.0 cm and contains multiple hemorrhagic cysts, measuring from 0.7 to 0.9 cm in greatest dimension. The right fallopian tube is 5.0 cm long, 0.5 cm in diameter, and is grossly unremarkable. The left ovary measures 2.5 x 2.0 x 1.7 cm and contains multiple smooth-walled serous cysts, measuring from 0.3 to 1.3 cm in greatest dimension. The left fallopian tube is 5.5 cm long, 0.6 cm in diameter, and is grossly unremarkable. Entirely submitted.

- A: anterior cervix-1
- B: posterior cervix-1
- C-D: right parametrium-5 each
- E-F: left parametrium-6 each
- G: anterior corpus uteri-1
- H-I: posterior corpus uteri-1 each
- J: right tube and ovary-2
- K: left tube and ovary-2

2. RIGHT PELVIC NODE

Labeled with the patient's name, labeled as designated on the specimen requisition form, and received in formalin is a portion of adipose tissue measuring 3.5 x 2.7 x 0.5 cm in greatest dimensions. Lymph node dissection reveals one, firm yellow-tan lymph node(s) measuring 1.2 x 0.9 x 0.3 cm in greatest dimensions. Entirely submitted.

- L: bisected lymph node-2

3. RIGHT PERIAORTIC LYMPH NODE

Labeled with the patient's name, labeled as designated on the specimen requisition form, and received in formalin is a portion of adipose tissue measuring 2.5 x 0.7 x 0.3 cm in greatest dimensions. Lymph node dissection reveals one, firm yellow-tan lymph node(s) measuring 2.5 x 0.5 x 0.3 cm in greatest dimensions. Entirely submitted.

- M: lymph node-1

4. LEFT PELVIC LYMPH NODE

Labeled with the patient's name, labeled as designated on the specimen requisition form, and received in formalin is an aggregate of adipose tissue measuring 3.5 x 2.4 x 0.3 cm in greatest dimensions. Lymph node dissection reveals one, firm yellow-tan lymph node(s) measuring 1.5 x 0.9 x 0.3 cm in greatest dimensions. Entirely submitted.

- N: lymph node-1

5. LEFT PA LYMPH NODE

Labeled with the patient's name, labeled as designated on the specimen requisition form, and received in formalin is a portion of

[page 3 of 3]
adipose tissue measuring 2.0 x 1.2 x 0.3 cm in greatest dimensions. Lymph node dissection reveals one, firm yellow-tan lymph node(s) measuring 0.7 x 0.3 x 0.3 cm in greatest dimensions. Entirely submitted.

O: bisected lymph node-2

6. APPENDIX

Labeled with the patient's name, labeled as designated on the specimen requisition form, and received in formalin is a vermiform appendix, 5.5 cm long and 0.6 cm in maximum diameter, with attached fat up to 1.2 cm in width and 0.8 cm in thickness. There are no apparent gross abnormalities. Representative sections.

P: 3

Gross dictated by _____, M.D.

Special Studies: None
See Also:

Pathologist

M.D.

I, _____ M.D., the pathologist of record, have personally examined the specimen, interpreted the results, reviewed this report and signed it electronically.
Date Finalled:

Source: NCI Genomic Data Commons file 4aa699ab-a368-4112-b688-2fdeaf24d027 (TCGA-A5-A0GE.7686A445-554F-43EF-BE79-6EA5E5C4DB21.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).